Somatic mutation profile of tumor specimen C3N-04176-07 (aliquot CPT0247390006) from CPTAC case C3N-04176, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,173 days).
Specimen C3N-04176-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a0a5b0a-e4f7-45bf-8720-995f691863d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04176-31 (Blood Derived Normal), aliquot CPT0247790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2476212-a449-453a-bfda-89627718fb49

The open-access MAF lists 1,618 somatic variants for this specimen: 1,109 protein-altering or splice-affecting, 312 silent, 197 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 923, Silent 312, Intron 82, Nonsense Mutation 71, Frame Shift Del 53, RNA 37, Splice Site 29, 3'UTR 28, 5'UTR 25, 5'Flank 14, Splice Region 13, In Frame Del 11.

Variants (750 of 1,618; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 59/178 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, varscan2
- ABCG8 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV53210230; called by muse, mutect2, varscan2
- ACAN | c.4627G>T p.G1543W | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV61362967; called by muse, mutect2, varscan2
- ACOXL | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as rs1253227828; called by muse, mutect2, varscan2
- ACSM2B | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV61659836; called by muse, mutect2, varscan2
- ACTC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99291526; called by muse, mutect2, varscan2
- ADAD1 | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV99636339; called by muse, mutect2, varscan2
- ADAM33 | c.332C>A p.T111K | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs146682885, COSV62934385; called by muse, mutect2, varscan2
- ADAMTS12 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61259397, COSV61263423; called by muse, mutect2, varscan2
- ADAMTS2 | c.2914C>A p.R972S | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867846785, COSV52368134; called by mutect2, varscan2
- ADAMTS6 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66857239; called by muse, mutect2, varscan2
- ADARB2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs137952643; called by muse, mutect2
- ADGRA1 | c.965C>A p.P322Q | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66924825, COSV66928075; called by muse, mutect2, varscan2
- ADGRA3 | c.1969G>C p.A657P | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs777307868; called by muse, mutect2, varscan2
- ADGRE2 | c.1872del p.F625Sfs*7 | Frame Shift Del (DEL) | VAF 106/481 reads (22%) | catalogued as COSV59691829; called by mutect2, pindel, varscan2
- ADGRG7 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs770055964; called by muse, mutect2, varscan2
- ADRA2A | c.688del p.V230Sfs*112 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV54529586; called by mutect2, pindel, varscan2
- AIM2 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs145420527; called by muse, mutect2, varscan2
- AKAP6 | c.6611C>T p.S2204L | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs756642987, COSV55228415; called by muse, mutect2, varscan2
- ALMS1 | c.2610C>A p.F870L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100043686; called by muse, mutect2, varscan2
- ALOX15 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs1301041526, COSV53396538; called by muse, mutect2, varscan2
- AMFR | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51923847; called by muse, mutect2, varscan2
- ANKRD12 | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as COSV100040933; called by muse, mutect2, varscan2
- ANKRD42 | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs140132570; called by muse, mutect2, varscan2
- ANO8 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs753044361; called by muse, mutect2, varscan2
- APBB1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 180/510 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV100194124; called by muse, varscan2
- APLNR | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.047); catalogued as COSV57241337; called by muse, mutect2, varscan2
- ARHGAP29 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 31/294 reads (11%) | catalogued as COSV53113432; called by muse, mutect2, varscan2
- ARPC5 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs777026263; called by muse, mutect2, varscan2
- ARSJ | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV100192460; called by muse, mutect2, varscan2
- ASPM | c.7187G>A p.R2396K | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs1464273099, COSV54127839; called by muse, mutect2, varscan2
- ATP1B4 | c.478G>T p.A160S (on ENST00000218008 / NM_001142447.3; = p.A156S on NM_012069.5) | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.518); catalogued as COSV54311680; called by muse, mutect2, varscan2
- ATXN7L3 | c.147_149del p.F49del | In Frame Del (DEL) | VAF 31/253 reads (12%) | catalogued as rs770628692; called by pindel, varscan2
- BCAS3 | c.2175+1G>T p.X725_splice (on ENST00000390652 / NM_001353144.2; = p.X710_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 38/94 reads (40%) | catalogued as rs1239831577; called by muse, mutect2, varscan2
- BEND3 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV64682130; called by muse, mutect2, varscan2
- BICDL2 | c.1162_1164del p.K388del | In Frame Del (DEL) | VAF 26/255 reads (10%) | catalogued as rs1312008483; called by mutect2, pindel
- BIRC6 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 143/291 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs756116235, COSV101427860; called by muse, mutect2, varscan2
- C10orf71 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100110749; called by muse, mutect2, varscan2
- C14orf28 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as rs749012560; called by mutect2, varscan2
- C16orf78 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768529256; called by muse, mutect2, varscan2
- CACNA1E | c.4334C>A p.A1445E | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62387510; called by muse, mutect2, varscan2
- CALHM6 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 60/264 reads (23%) | catalogued as rs762477294; called by muse, mutect2
- CATSPERE | c.153G>C p.W51C | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63680512; called by muse, mutect2
- CCDC114 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100196758; called by muse, mutect2, varscan2
- CCDC88C | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1448061729, COSV66240047; called by muse, mutect2, varscan2
- CCKAR | c.883C>A p.R295S | Missense Mutation (SNP) | VAF 186/517 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as rs756393377; called by muse, mutect2, varscan2
- CDH26 | c.2347G>T p.V783F (on ENST00000348616 / NM_177980.4; = p.V116F on NM_021810.6) | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV54852971, COSV54853000; called by muse, mutect2, varscan2
- CDH7 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs559383536; called by muse, varscan2
- CDH9 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV50538651; called by muse, mutect2, varscan2
- CENPF | c.8984G>T p.G2995V | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65277448; called by muse, mutect2, varscan2
- CEP126 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs1222290904; called by muse, mutect2
- CFAP206 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV51537514; called by muse, mutect2, varscan2
- CHCHD2 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV101271061; called by muse, mutect2
- CHIT1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs575619015; called by muse, mutect2, varscan2
- CLCN1 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 349/996 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076114; called by muse, mutect2, varscan2
- CLDN19 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 206/523 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs752086015, COSV56417546; called by muse, mutect2, varscan2
- CLSTN2 | c.2726C>A p.A909D | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs1416573055; called by muse, varscan2
- COL20A1 | c.3498G>T p.E1166D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs558869563; called by muse, mutect2, varscan2
- COL22A1 | c.2255del p.P752Lfs*63 | Frame Shift Del (DEL) | VAF 60/247 reads (24%) | catalogued as rs1172435290; called by mutect2, pindel, varscan2
- COL2A1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1023703904, COSV61531680; called by muse, mutect2, varscan2
- COL4A6 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57878732; called by muse, mutect2, varscan2
- COL9A1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 114/418 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57885303; called by muse, mutect2, varscan2
- CPN1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 70/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540311121; called by muse, mutect2, varscan2
- CR1 | c.5108C>A p.A1703D | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV65457488; called by muse, mutect2, varscan2
- CRAMP1 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.03); catalogued as COSV53523675; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV65678151; called by muse, mutect2
- CSMD1 | c.2317C>A p.P773T (on ENST00000520002; = p.P772T on NM_033225.6) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100148096; called by muse, mutect2, varscan2
- CSMD3 | c.3234C>G p.I1078M (on ENST00000297405 / NM_001363185.1; = p.I974M on NM_052900.3) | Missense Mutation (SNP) | VAF 53/604 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52124854, COSV99842025; called by muse, mutect2
- CST11 | c.400A>C p.S134R (on ENST00000377009 / NM_130794.2; = p.S99R on NM_080830.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV65441289; called by muse, mutect2, varscan2
- CTAGE6 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 90/2402 reads (4%) | catalogued as COSV69917278; called by muse, mutect2
- CTCF | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV50462386; called by muse, mutect2
- CYB5R1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100924825; called by muse, mutect2, varscan2
- DACT1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 76/532 reads (14%) | catalogued as COSV60019761, COSV60022605; called by muse, mutect2, varscan2
- DCAF12L2 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs753083215, COSV100758539, COSV63582082; called by muse, mutect2, varscan2
- DCDC1 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV60838595; called by muse, mutect2, varscan2
- DCHS2 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1054943474; called by muse, mutect2, varscan2
- DDN | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100305395; called by muse, mutect2, varscan2
- DEK | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV55240086; called by muse, varscan2
- DGKB | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335299; called by muse, mutect2, varscan2
- DGKI | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.018); catalogued as rs769151879; called by muse, mutect2, varscan2
- DLGAP2 | c.1578C>A p.S526R | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70103927; called by muse, mutect2, varscan2
- DNAAF4 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100336585; called by muse, mutect2, varscan2
- DNAH3 | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235481287; called by muse, mutect2, varscan2
- DNAH5 | c.7574G>C p.G2525A | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV54213785; called by muse, mutect2, varscan2
- DOCK5 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV99377482; called by muse, mutect2, varscan2
- DSCAML1 | c.6049C>T p.H2017Y (on ENST00000321322; = p.H1957Y on NM_020693.4) | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.327); catalogued as rs1468762831, COSV100357412; called by muse, mutect2, varscan2
- DSCAML1 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs1208666557; called by muse, mutect2, varscan2
- DSEL | c.1037G>T p.W346L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100025206; called by muse, mutect2, varscan2
- DST | c.6101C>T p.T2034I | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1193936947; called by muse, mutect2
- EPHA3 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100347249; called by muse, mutect2, varscan2
- EPHB1 | c.1756C>G p.R586G | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67661962, COSV67663055; called by muse, mutect2, varscan2
- EPHB1 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101212708, COSV67657416; called by muse, mutect2, varscan2
- EPHB1 | c.2775G>T p.M925I | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs56111847; called by muse, mutect2, varscan2
- EPHB4 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV100639418; called by muse, mutect2
- ERCC6 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 117/480 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100875589; called by muse, mutect2, varscan2
- FAM184B | c.1125C>A p.S375R | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs775559952; called by muse, mutect2, varscan2
- FAM47A | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60499148; called by muse, mutect2, varscan2
- FAM83B | c.1271G>C p.S424T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV60924981; called by muse, mutect2, varscan2
- FAM83B | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60926359; called by muse, mutect2, varscan2
- FAM90A1 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 153/1069 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.342); catalogued as rs1247264883; called by muse, mutect2, varscan2
- FGFR3 | c.*1330+1G>T | Splice Site (SNP) | VAF 102/397 reads (26%) | catalogued as rs777159230; called by muse, mutect2, varscan2
- FHL5 | c.762del p.K254Nfs*12 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as COSV58737019; called by mutect2, pindel, varscan2
- FLACC1 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as COSV53788617; called by muse, mutect2, varscan2
- FLNC | c.5669-3C>T | Splice Region (SNP) | VAF 154/384 reads (40%) | catalogued as rs1563001545; called by muse, mutect2, varscan2
- FMN2 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60417101; called by muse, mutect2, varscan2
- FNDC1 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781072694; called by muse, mutect2, varscan2
- FOXP2 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 104/474 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs761174159; called by muse, varscan2
- FRMPD3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750463805, COSV52188915; called by muse, mutect2, varscan2
- FSTL4 | c.2479G>T p.V827L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.43); catalogued as COSV99533383; called by muse, mutect2, varscan2
- GABRG1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54953934, COSV99777743; called by muse, mutect2, varscan2
- GAP43 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100525743; called by muse, mutect2, varscan2
- GAPDHS | c.540G>C p.S180= | Splice Region (SNP) | VAF 63/266 reads (24%) | catalogued as COSV99722507; called by muse, mutect2, varscan2
- GCFC2 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as rs1294074905, COSV100319261; called by muse, mutect2, varscan2
- GNA15 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99505114; called by muse, mutect2
- GNB3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs782370043; called by muse, mutect2, varscan2
- GP2 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV100221381; called by muse, mutect2, varscan2
- GPC3 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63658177; called by muse, mutect2, varscan2
- GPR158 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66284627; called by muse, mutect2, varscan2
- GPR158 | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66276097, COSV66280618; called by muse, mutect2, varscan2
- GRM6 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51435848, COSV51436532; called by muse, mutect2, varscan2
- HBE1 | c.108C>A p.Y36* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as rs1274644435; called by muse, mutect2, varscan2
- HDAC9 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 59/168 reads (35%) | catalogued as COSV67775658; called by muse, mutect2, varscan2
- HEPACAM2 | c.821C>T p.S274F (on ENST00000394468 / NM_001039372.4; = p.S262F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59064002; called by muse, mutect2
- HEPH | c.590C>A p.T197N (on ENST00000343002; = p.T251N on NM_138737.5) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV57963825; called by muse, mutect2, varscan2
- HEPH | c.1642G>T p.D548Y (on ENST00000343002; = p.D281Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295986; called by muse, mutect2, varscan2
- HNRNPDL | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1044734748; called by muse, mutect2, varscan2
- HPSE2 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV65186028; called by muse, mutect2, varscan2
- HRNR | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 132/464 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs747884891, COSV100913846, COSV64255415; called by muse, mutect2, varscan2
- HSFX2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1422106018; called by muse, mutect2, varscan2
- HTR1B | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs758287426, COSV64051364; called by muse, mutect2, varscan2
- HYDIN | c.14582C>A p.S4861* | Nonsense Mutation (SNP) | VAF 108/455 reads (24%) | catalogued as COSV66641460; called by muse, mutect2, varscan2
- IGHV4-34 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs767886813; called by muse, mutect2, varscan2
- IGKV2D-29 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV72391532; called by muse, mutect2, varscan2
- IGSF5 | c.956+2T>C p.X319_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | catalogued as rs149173446; called by muse, mutect2, varscan2
- IKBKE | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV65624649; called by muse, mutect2, varscan2
- IL13RA2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs370152207; called by muse, mutect2, varscan2
- IRGC | c.223C>G p.R75G | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99746210; called by muse, mutect2, varscan2
- IRS4 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 56/452 reads (12%) | catalogued as rs777926043, COSV100929699, COSV64535062; called by muse, mutect2, varscan2
- IRX3 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 76/319 reads (24%) | catalogued as COSV100315208; called by muse, mutect2, varscan2
- ITGAM | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs757551647, COSV54940309; called by muse, mutect2, varscan2
- ITGB1 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56480972; called by muse, mutect2, varscan2
- ITGB8 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV56005590, COSV56015637; called by muse, mutect2, varscan2
- ITPKB | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1424240399; called by muse, mutect2, varscan2
- KCNB1 | c.1470G>T p.W490C | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); catalogued as COSV65566888; called by muse, mutect2, varscan2
- KCNMA1 | c.2654A>G p.Y885C (on ENST00000286628 / NM_001161352.2; = p.Y827C on NM_002247.4) | Missense Mutation (SNP) | VAF 82/601 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1303405042; called by muse, mutect2, varscan2
- KERA | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); catalogued as COSV99899316; called by muse, mutect2, varscan2
- KHNYN | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV99250268; called by muse, mutect2
- KIF13A | c.1661A>T p.D554V | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs962986544; called by muse, mutect2, varscan2
- KIF15 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1174829320; called by muse, mutect2, varscan2
- KIF21A | c.4813G>A p.G1605R (on ENST00000361418 / NM_001378440.1; = p.G1592R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62769932, COSV62777891; called by muse, mutect2, varscan2
- KIF3B | c.2152A>G p.K718E | Missense Mutation (SNP) | VAF 71/551 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.899); catalogued as rs1337217117; called by muse, mutect2, varscan2
- KLHL38 | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 157/517 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58088662; called by muse, mutect2, varscan2
- KLHL6 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as rs932549092, COSV58067601; called by muse, mutect2, varscan2
- KPNA4 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100515159; called by muse, mutect2, varscan2
- KRTAP4-3 | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 161/507 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs1240669306; called by muse, varscan2
- KSR2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1317477250; called by muse, mutect2, varscan2
- LAMB4 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs753754788; called by muse, mutect2
- LAMC3 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 96/293 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1249343175; called by muse, mutect2, varscan2
- LBP | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.154); catalogued as COSV99461346; called by muse, mutect2, varscan2
- LCMT2 | c.1943_1945del p.L648del | In Frame Del (DEL) | VAF 36/231 reads (16%) | catalogued as rs567418780; called by pindel, varscan2
- LDLR | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as CM013567, CM091470; called by muse, mutect2, varscan2
- LGSN | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV65726386; called by muse, varscan2
- LMNB1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV54397369; called by muse, mutect2, varscan2
- LMX1A | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54227112, COSV54228049; called by muse, mutect2, varscan2
- LNPK | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1241394082; called by muse, mutect2, varscan2
- LRFN2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs747904724, COSV57835638; called by muse, mutect2, varscan2
- LRFN5 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV53260542; called by muse, mutect2, varscan2
- LRP1 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435365628; called by muse, mutect2, varscan2
- LRP12 | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as COSV52629757; called by muse, mutect2, varscan2
- LRP1B | c.10117G>A p.A3373T | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV67210726; called by muse, mutect2, varscan2
- LRP1B | c.5759-1G>T p.X1920_splice | Splice Site (SNP) | VAF 27/76 reads (36%) | catalogued as COSV101253618; called by muse, varscan2
- LRRC37B | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 207/447 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100496264; called by muse, mutect2, varscan2
- LRRTM3 | c.1297G>T p.V433F | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.696); catalogued as COSV63671479; called by muse, mutect2, varscan2
- LRTM2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as COSV54564764; called by muse, mutect2, varscan2
- M1AP | c.845G>T p.R282I | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99304607; called by muse, mutect2, varscan2
- MAGEC3 | c.1497del p.A501Pfs*5 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | catalogued as COSV68924187; called by mutect2, pindel, varscan2
- MAP2K4 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62258784; called by muse, mutect2, varscan2
- MAP7 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV100643982; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.193); catalogued as rs1281599271; called by muse, mutect2, varscan2
- MCF2L2 | c.3004G>T p.G1002* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as COSV61054256; called by muse, mutect2, varscan2
- ME3 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | catalogued as rs199559518, COSV62773610; called by muse, mutect2, varscan2
- MEOX2 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 166/563 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56294310; called by muse, mutect2, varscan2
- MGAM2 | c.4238G>T p.S1413I | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.591); catalogued as rs1049792309; called by muse, mutect2, varscan2
- MICAL3 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs368124560; called by muse, mutect2, varscan2
- MNDA | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.468); catalogued as COSV63740837; called by muse, mutect2
- MNX1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 127/778 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM003827, CM1311809; called by muse, mutect2, varscan2
- MSH3 | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1451464888, COSV99435838; called by muse, mutect2, varscan2
- MTA3 | c.1023C>T p.T341= | Splice Region (SNP) | VAF 17/69 reads (25%) | catalogued as rs1306958546; called by muse, mutect2, varscan2
- MTX3 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV72512506; called by muse, mutect2, varscan2
- MUC19 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.81); catalogued as rs993899468; called by muse, mutect2, varscan2
- MYH4 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 174/556 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV55125947; called by muse, mutect2, varscan2
- MYOT | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 101/296 reads (34%) | catalogued as COSV53516196; called by muse, mutect2, varscan2
- NCAM1 | c.1954-1G>A p.X652_splice (on ENST00000316851 / NM_181351.5; = p.X642_splice on NM_000615.7) | Splice Site (SNP) | VAF 12/87 reads (14%) | catalogued as rs1482935407; called by muse, mutect2, varscan2
- NCOA1 | c.3881+1G>C p.X1294_splice | Splice Site (SNP) | VAF 32/109 reads (29%) | catalogued as COSV99945470; called by muse, mutect2, varscan2
- NDUFC2 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421063535; called by muse, mutect2
- NLRP4 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.685); catalogued as rs751496645, COSV56721164; called by muse, mutect2
- NONO | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV52136937, COSV52136980; called by muse, mutect2, varscan2
- NOX3 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV50158568; called by muse, mutect2
- NPAS3 | c.1825G>T p.G609C (on ENST00000356141 / NM_001164749.2; = p.G577C on NM_022123.3) | Missense Mutation (SNP) | VAF 74/496 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs766694241, COSV100640411; called by muse, mutect2, varscan2
- NPC1L1 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148698796; called by muse, mutect2, varscan2
- NSD1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61777590; called by muse, mutect2, varscan2
- NXPH4 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 135/579 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61075408; called by muse, mutect2, varscan2
- OCA2 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 112/529 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV62341550; called by muse, mutect2, varscan2
- OLFM2 | c.884C>A p.S295* | Nonsense Mutation (SNP) | VAF 10/235 reads (4%) | catalogued as rs925669211; called by muse, mutect2
- OR10K1 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 97/407 reads (24%) | catalogued as COSV99193832; called by muse, mutect2, varscan2
- OR10K1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56874039; called by muse, mutect2, varscan2
- OR10Z1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 84/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63526530; called by muse, mutect2, varscan2
- OR11H1 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV53272671; called by mutect2, varscan2
- OR11L1 | c.191A>T p.Q64L | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1226612143; called by muse, mutect2, varscan2
- OR14A16 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.135); catalogued as COSV62927031; called by muse, mutect2
- OR2A5 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1458103884; called by muse, mutect2
- OR2M2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 122/433 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs746047467, COSV62897776; called by muse, mutect2, varscan2
- OR4F6 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); catalogued as rs752159724; called by muse, mutect2
- OR4K2 | c.840del p.T281Lfs*2 | Frame Shift Del (DEL) | VAF 50/302 reads (17%) | catalogued as COSV100063945; called by mutect2, pindel, varscan2
- OR4K5 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 39/318 reads (12%) | catalogued as rs770657104, COSV60003714; called by muse, mutect2, varscan2
- OR4X2 | c.213del p.K72Nfs*38 | Frame Shift Del (DEL) | VAF 53/168 reads (32%) | catalogued as rs757093215; called by mutect2, pindel, varscan2
- OR51A4 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 152/590 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100985332; called by muse, mutect2, varscan2
- OR52E4 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100389117; called by muse, mutect2, varscan2
- OR5AC2 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV62280050; called by muse, mutect2, varscan2
- OR5M11 | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.873); catalogued as COSV73142027; called by muse, mutect2, varscan2
- OR6N1 | c.203T>A p.F68Y | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs777866494; called by muse, mutect2, varscan2
- OR6N1 | c.17G>T p.W6L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58650273; called by muse, mutect2, varscan2
- OR8G5 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.024); catalogued as COSV58381582; called by muse, mutect2
- OTOL1 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs1413494616; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1130A>G p.N377S | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1167470350; called by muse, mutect2, varscan2
- PAPOLA | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV53478884; called by muse, mutect2, varscan2
- PCDH15 | c.3441A>C p.K1147N | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV100225432; called by muse, mutect2
- PCDH15 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 99/506 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100229152, COSV57372533; called by muse, mutect2, varscan2
- PCDHA11 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as rs782072957, COSV56498697; called by muse, mutect2, varscan2
- PCDHB16 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 225/656 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); catalogued as rs782473692; called by muse, mutect2, varscan2
- PCDHGA9 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as rs200601931; called by muse, mutect2, varscan2
- PCNX1 | c.4727G>A p.R1576Q | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs878892097, COSV99031984; called by muse, mutect2, varscan2
- PCNX2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50849897; called by muse, mutect2, varscan2
- PDE10A | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV63096244; called by muse, mutect2, varscan2
- PDHA2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV54779225; called by muse, mutect2, varscan2
- PDZD2 | c.6503C>T p.A2168V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs987793122; called by muse, mutect2, varscan2
- PDZD7 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV64647452; called by muse, mutect2, varscan2
- PEG10 | c.766G>A p.A256T (on ENST00000482108 / NM_001040152.2; = p.A290T on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV71788676; called by muse, mutect2, varscan2
- PER3 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV62707293; called by muse, mutect2, varscan2
- PEX6 | c.1401_1403del p.L468del | In Frame Del (DEL) | VAF 96/309 reads (31%) | catalogued as rs1222318292; called by mutect2, pindel, varscan2
- PHLDB2 | c.3502G>T p.D1168Y (on ENST00000393925 / NM_001134439.2; = p.D1125Y on NM_145753.2) | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182878056, COSV67310233, COSV67312866; called by muse, mutect2, varscan2
- PJA1 | c.1039G>T p.D347Y (on ENST00000361478 / NM_145119.4; = p.D159Y on NM_022368.5) | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64052956; called by muse, mutect2, varscan2
- PKD1L1 | c.7798G>T p.D2600Y | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51845494; called by muse, mutect2, varscan2
- PLA2G2C | c.110_112del p.F37del | In Frame Del (DEL) | VAF 40/191 reads (21%) | catalogued as rs772948292; called by pindel, varscan2
- PLD5 | c.1605C>A p.N535K (on ENST00000442594; = p.N473K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100138693; called by muse, mutect2, varscan2
- PLIN3 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99701794; called by muse, mutect2, varscan2
- PLPPR4 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 26/202 reads (13%) | catalogued as COSV64567141; called by muse, mutect2, varscan2
- PLXNA4 | c.4673G>T p.G1558V | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100323692; called by muse, mutect2, varscan2
- PLXNB3 | c.4039G>A p.G1347S | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs142851201; called by muse, mutect2, varscan2
- PNCK | c.450C>A p.D150E (on ENST00000340888 / NM_001366975.1; = p.D233E on NM_001039582.3) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.545); catalogued as COSV61745178; called by muse, mutect2, varscan2
- POSTN | c.1465C>A p.R489S | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.069); catalogued as COSV65712393; called by muse, mutect2, varscan2
- POU6F1 | c.1440G>T p.Q480H | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100374735; called by muse, mutect2, varscan2
- PPP1R3A | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV52895044; called by muse, mutect2, varscan2
- PRAMEF19 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 123/1307 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1392294846; called by muse, mutect2
- PRDM9 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 150/679 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV57001953; called by muse, mutect2, varscan2
- PRKCB | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV57776596, COSV57783158; called by muse, mutect2, varscan2
- PRPF38B | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV64223876; called by muse, mutect2, varscan2
- PRR23C | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs907640571; called by muse, varscan2
- PSMD4 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 49/208 reads (24%) | catalogued as COSV100924640; called by muse, mutect2, varscan2
- PTPN13 | c.6196G>T p.D2066Y (on ENST00000411767 / NM_080683.3; = p.D2047Y on NM_006264.3) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1400338936; called by muse, mutect2, varscan2
- PTPRC | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs755859528; called by muse, mutect2
- PTPRH | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs544465704; called by muse, mutect2
- PTPRN2 | c.1198G>T p.G400W | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67061205; called by muse, mutect2
- RAI1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.484); catalogued as COSV55396149; called by muse, mutect2, varscan2
- RANBP2 | c.140+1G>T p.X47_splice | Splice Site (SNP) | VAF 38/171 reads (22%) | catalogued as rs1382578906; called by muse, mutect2, varscan2
- RASAL3 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs1294982717; called by muse, mutect2, varscan2
- RASGRF2 | c.1681G>C p.A561P | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as COSV54128496; called by muse, mutect2, varscan2
- RECQL4 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 157/552 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52878517; called by muse, mutect2, varscan2
- REG1B | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59305802, COSV59307627; called by muse, mutect2, varscan2
- RESF1 | c.4144G>C p.V1382L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV57020437; called by muse, mutect2, varscan2
- RGS6 | c.1215C>A p.H405Q | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100665332; called by muse, mutect2, varscan2
- RIBC1 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141300771, COSV51448327; called by muse, mutect2
- RNF213 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.464); catalogued as rs1180914121; called by muse, mutect2, varscan2
- ROBO3 | c.2695G>T p.A899S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs771821278; called by muse, mutect2, varscan2
- RRP1B | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs756773603; called by muse, varscan2
- RTF2 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs758627888, COSV50127988; called by muse, mutect2, varscan2
- RTL9 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV71826241; called by muse, mutect2, varscan2
- RYR1 | c.5464G>C p.G1822R | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100614822, COSV62113655; called by muse, mutect2, varscan2
- RYR3 | c.4428G>T p.R1476S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV66790605; called by muse, mutect2, varscan2
- SAGE1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV61012395, COSV61013241; called by muse, mutect2, varscan2
- SASH1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs146881999; called by muse, mutect2, varscan2
- SCART1 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 100/591 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.606); catalogued as COSV100741579; called by muse, mutect2, varscan2
- SDK2 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs766912066, COSV66191205; called by muse, mutect2, varscan2
- SEPTIN12 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51616775; called by muse, mutect2, varscan2
- SEPTIN8 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); catalogued as rs763323893; called by muse, mutect2, varscan2
- SERPINA4 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372588655; called by muse, mutect2, varscan2
- SH3RF3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as rs754445900; called by muse, mutect2, varscan2
- SHANK2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 67/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575863; called by muse, mutect2, varscan2
- SHANK2 | c.1699A>T p.S567C | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99571977; called by muse, mutect2, varscan2
- SKOR2 | c.1984C>A p.H662N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs746722236; called by muse, mutect2, varscan2
- SLC14A2 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99675627; called by muse, mutect2, varscan2
- SLC25A43 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54217358; called by muse, mutect2, varscan2
- SLC26A5 | c.1311+1G>T p.X437_splice | Splice Site (SNP) | VAF 205/657 reads (31%) | catalogued as rs775034495; called by muse, mutect2, varscan2
- SLC28A2 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61663294; called by muse, mutect2, varscan2
- SLC4A4 | c.1242G>T p.Q414H (on ENST00000264485 / NM_001098484.3; = p.Q370H on NM_003759.4) | Missense Mutation (SNP) | VAF 102/396 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV99138800; called by muse, mutect2, varscan2
- SLC4A4 | c.1661G>T p.R554L (on ENST00000264485 / NM_001098484.3; = p.R510L on NM_003759.4) | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM992672; called by muse, mutect2, varscan2
- SLC6A15 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57029568; called by mutect2, varscan2
- SLCO5A1 | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 84/265 reads (32%) | catalogued as rs1207118593; called by muse, mutect2, varscan2
- SMOC2 | c.1096G>T p.D366Y (on ENST00000356284 / NM_001166412.2; = p.D377Y on NM_022138.3) | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV104418071; called by muse, mutect2
- SNED1 | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.047); catalogued as rs376698613; called by muse, mutect2, varscan2
- SPAM1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145111, COSV56146457; called by muse, mutect2, varscan2
- SPATA31E1 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100350102; called by muse, mutect2, varscan2
- SPATC1 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs782568671, COSV66298114; called by muse, mutect2, varscan2
- SPEF2 | c.3706G>C p.D1236H | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61554876; called by muse, mutect2, varscan2
- SPRR2E | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 82/582 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as rs1364460234; called by muse, varscan2
- SPRYD3 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99041588; called by muse, mutect2, varscan2
- SSTR4 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.37); catalogued as COSV54797077; called by muse, mutect2, varscan2
- ST6GAL2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | PolyPhen probably damaging (0.984); catalogued as rs865916184, COSV62415997; called by muse, mutect2
- STAG2 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54358349, COSV99492729; called by muse, mutect2, varscan2
- STYXL2 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs769931637, COSV54805835; called by muse, mutect2, varscan2
- SULT4A1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | catalogued as COSV50782546; called by muse, mutect2, varscan2
- SUPT20HL1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1220802219; called by muse, mutect2
- SUSD4 | c.258A>T p.Q86H | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1172801928, COSV100663791; called by muse, mutect2, varscan2
- SYNE1 | c.2369C>T p.S790L (on ENST00000367255 / NM_182961.4; = p.S797L on NM_033071.3) | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1439404297; called by muse, mutect2, varscan2
- SYTL4 | c.1966G>T p.G656W | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342937; called by muse, mutect2
- TANGO6 | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV99936128; called by muse, mutect2, varscan2
- TAOK1 | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55588211; called by muse, mutect2, varscan2
- TARM1 | c.253G>T p.E85* (on ENST00000616041 / NM_001330650.1; = p.E77* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 123/362 reads (34%) | catalogued as COSV71524949; called by muse, mutect2, varscan2
- TBC1D8B | c.1475T>G p.L492* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as COSV52179472; called by muse, mutect2, varscan2
- TCEA1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as rs760444974; called by mutect2, varscan2
- TCEA3 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65841383; called by muse, mutect2, varscan2
- TENM1 | c.3356G>T p.R1119M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64436313, COSV64442895; called by muse, mutect2, varscan2
- TENM3 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1324480533, COSV69301962, COSV69311034; called by muse, mutect2, varscan2
- TERB1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs187027418; called by muse, mutect2, varscan2
- TEX13C | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV66708663; called by muse, mutect2, varscan2
- TFAP2B | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 108/409 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1343878387; called by muse, mutect2, varscan2
- TFAP2D | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV50415735; called by muse, mutect2, varscan2
- TIMMDC1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as rs1184653027; called by muse, mutect2, varscan2
- TKTL2 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54919865, COSV54920168; called by muse, mutect2
- TMEM132D | c.1691G>T p.R564M | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV67163296; called by muse, mutect2
- TMEM132E | c.950G>A p.R317Q (on ENST00000321639; = p.R407Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as rs376665855; called by muse, mutect2, varscan2
- TMPPE | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs992755520; called by muse, mutect2, varscan2
- TNN | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 109/553 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.21); catalogued as rs1323229153, COSV53424960; called by muse, mutect2, varscan2
- TNN | c.2119+1G>T p.X707_splice | Splice Site (SNP) | VAF 69/288 reads (24%) | catalogued as rs1048134498, COSV53432502; called by muse, mutect2, varscan2
- TNR | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.225); catalogued as rs778290581, COSV54873859, COSV54893016; called by muse, mutect2, varscan2
- TOX2 | c.764C>T p.P255L (on ENST00000358131 / NM_001098798.2; = p.P204L on NM_032883.3) | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755479356; called by muse, mutect2, varscan2
- TP63 | c.709G>T p.V237F | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53200846; called by muse, mutect2, varscan2
- TRPC5 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53289485; called by muse, mutect2, varscan2
- TRPM4 | c.2512G>T p.G838C | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV53260436; called by muse, mutect2, varscan2
- TRPM5 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50157739; called by muse, mutect2, varscan2
- TSHZ2 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100296482; called by muse, varscan2
- TTC17 | c.1635_1637del p.E546del | In Frame Del (DEL) | VAF 24/172 reads (14%) | catalogued as rs769935672; called by pindel, varscan2
- TTN | c.67403G>T p.G22468V (on ENST00000591111; = p.G15044V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | PolyPhen probably damaging (0.967); catalogued as COSV59957633; called by muse, mutect2, varscan2
- UBQLN3 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV100293502; called by muse, mutect2, varscan2
- UNC13A | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV53214039; called by muse, mutect2, varscan2
- UNC5D | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54847167; called by muse, mutect2, varscan2
- UVRAG | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765996254; called by muse, mutect2, varscan2
- VAV1 | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58391341; called by muse, mutect2, varscan2
- VGF | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV99973234; called by muse, mutect2
- VPS9D1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 64/536 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557032960; called by muse, varscan2
- VSIG8 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 58/181 reads (32%) | catalogued as rs1203186597; called by mutect2, varscan2
- WDR49 | c.1099G>T p.E367* (on ENST00000308378 / NM_001366158.1; = p.E708* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/277 reads (14%) | catalogued as COSV100393401, COSV57713045; called by muse, mutect2, varscan2
- WDR86 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 176/433 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1340952111; called by muse, mutect2, varscan2
- XIRP2 | c.8002C>T p.H2668Y (on ENST00000628543; = p.H2843Y on NM_152381.6) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1395076409; called by muse, mutect2, varscan2
- YKT6 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs764130626; called by muse, mutect2, varscan2
- YLPM1 | c.5297A>G p.Y1766C | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1243495568; called by muse, mutect2, varscan2
- ZC3H4 | c.3754G>T p.V1252L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV99452183; called by muse, mutect2, varscan2
- ZCCHC2 | c.1828C>T p.H610Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.172); catalogued as rs1271942346; called by muse, mutect2, varscan2
- ZEB2 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV57968893; called by muse, mutect2, varscan2
- ZFHX4 | c.4577G>T p.G1526V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50557067, COSV50756866; called by muse, mutect2, varscan2
- ZFYVE26 | c.5441C>T p.T1814I | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1178988794; called by muse, mutect2, varscan2
- ZNF141 | c.865A>G p.R289G | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782777606; called by muse, mutect2, varscan2
- ZNF148 | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 15/91 reads (16%) | catalogued as rs762887699, COSV100642150; called by muse, mutect2, varscan2
- ZNF267 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs538888358; called by muse, mutect2, varscan2
- ZNF398 | c.1303C>T p.R435C (on ENST00000475153 / NM_170686.3; = p.R264C on NM_020781.4) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs758135020; called by muse, mutect2
- ZNF516 | c.2863G>T p.V955F | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as rs781018561; called by muse, mutect2
- ZNF536 | c.230T>A p.M77K | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV62835757; called by muse, mutect2, varscan2
- ZNF555 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1219091898; called by muse, mutect2, varscan2
- ZNF560 | c.530-1G>T p.X177_splice | Splice Site (SNP) | VAF 33/129 reads (26%) | catalogued as COSV56867007, COSV56868860; called by muse, mutect2, varscan2
- ZNF574 | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV99726118; called by muse, mutect2, varscan2
- ZNF607 | c.147del p.V50Yfs*6 | Frame Shift Del (DEL) | VAF 41/181 reads (23%) | catalogued as rs1568406070, COSV62206594; called by mutect2, pindel, varscan2
- ZNF616 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV57512421; called by muse, mutect2, varscan2
- ZNF687 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1191446189; called by muse, mutect2, varscan2
- ZNF717 | c.1520A>G p.Y507C | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1307398876; called by muse, mutect2
- ZNF729 | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 131/710 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.05); catalogued as rs1477371437; called by muse, varscan2
- ZNF837 | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs1480167732; called by muse, mutect2, varscan2
- ZNF862 | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1554450745; called by muse, mutect2
- ZNF99 | c.2330G>C p.R777T | Missense Mutation (SNP) | VAF 117/602 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1568382576, COSV68055925, COSV68056592; called by muse, mutect2, varscan2
- ABCC10 | c.4181G>T p.R1394M (on ENST00000372530 / NM_001198934.2; = p.R1366M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCF3 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCG1 | c.1379_1381del p.F460del | In Frame Del (DEL) | VAF 34/297 reads (11%) | called by pindel, varscan2
- ABHD8 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACKR1 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ACOT1 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 94/652 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ACTR3 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ADAM15 | c.2314A>T p.R772W | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM28 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMDEC1 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2
- ADAMTS20 | c.3953G>C p.S1318T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2
- ADAMTSL1 | c.2665C>A p.L889M | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2734C>A p.P912T | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ADCY2 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- ADCY2 | c.3123G>A p.Q1041= | Splice Region (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- ADGB | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ADGB | c.742del p.A248Qfs*7 | Frame Shift Del (DEL) | VAF 46/122 reads (38%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.528C>G p.H176Q | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ADGRF2 | c.454G>T p.A152S (on ENST00000296862 / NM_001368115.2; = p.A84S on NM_153839.7) | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2
- ADGRG1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 145/619 reads (23%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4720C>A p.P1574T | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- ADGRG4 | c.5298G>T p.Q1766H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADGRG6 | c.3530C>G p.S1177C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG7 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.3466G>A p.D1156N (on ENST00000370717 / NM_001366005.1; = p.D1143N on NM_012302.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL3 | c.2361G>C p.M787I (on ENST00000506720 / NM_001322402.2; = p.M719I on NM_015236.6) | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL4 | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AFF2 | c.935A>T p.E312V | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AFF2 | c.3892C>A p.R1298S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.8804C>G p.P2935R | Missense Mutation (SNP) | VAF 73/560 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- AKR1C1 | c.600A>C p.R200S | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL021368.4 | n.219G>T | Splice Region (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- ALPK1 | c.2096A>T p.Q699L | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALPK2 | c.6428C>A p.P2143Q | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- AMZ1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK1 | c.5256G>T p.K1752N | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.4543T>A p.S1515T | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.5745G>T p.M1915I | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ANKRD33B | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2
- AP1M2 | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- AQP10 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF28 | c.2737G>T p.E913* | Nonsense Mutation (SNP) | VAF 77/210 reads (37%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASCC1 | c.656A>G p.E219G (on ENST00000342444 / NM_001369085.1; = p.E191G on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/554 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ASH1L | c.2794A>C p.S932R | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASMTL | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 33/204 reads (16%) | called by muse, mutect2, varscan2
- ASTN2 | c.1270A>T p.S424C (on ENST00000313400 / NM_001365069.1; = p.S373C on NM_014010.5) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATG14 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 100/331 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG4A | c.975A>T p.K325N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP11A | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ATP11C | c.2879T>A p.L960* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- ATP13A3 | c.3111G>T p.W1037C | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP8B4 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GNT6 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- BCL11B | c.1121G>T p.S374I (on ENST00000357195 / NM_001282237.2; = p.S303I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- BCLAF1 | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BEX3 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- BICDL1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- BMP6 | c.1073T>A p.F358Y | Missense Mutation (SNP) | VAF 54/573 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMPR1B | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BMX | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB3 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 34/274 reads (12%) | called by muse, mutect2, varscan2
- BRAF | c.1462G>T p.D488Y (on ENST00000288602 / NM_001374244.1; = p.D448Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/529 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BRINP2 | c.892A>C p.K298Q | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BST1 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7 | c.1145C>G p.A382G | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C7 | c.1824C>A p.N608K | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CA1 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA12 | c.783C>A p.H261Q | Missense Mutation (SNP) | VAF 165/495 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CALHM1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALHM6 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- CALM2 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CARD11 | c.1971del p.H658Tfs*14 | Frame Shift Del (DEL) | VAF 39/172 reads (23%) | called by mutect2, pindel
- CARMIL3 | c.838_839del p.L280Vfs*72 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by pindel, varscan2
- CASP5 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 73/317 reads (23%) | called by muse, mutect2, varscan2
- CCDC168 | c.15134C>A p.T5045N | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC180 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
- CCDC3 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC54 | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCL23 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- CCNB1IP1 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCSER1 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CCSER1 | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CD84 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH18 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CDH2 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- CDH26 | c.2098G>T p.D700Y (on ENST00000348616 / NM_177980.4; = p.D33Y on NM_021810.6) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CDH8 | c.689C>G p.P230R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); called by muse, mutect2
- CDKAL1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CDO1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CDYL | c.1150G>T p.A384S (on ENST00000328908 / NM_001368125.1; = p.A330S on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CEACAM6 | c.762_766del p.N254Kfs*9 | Frame Shift Del (DEL) | VAF 56/378 reads (15%) | called by mutect2, pindel, varscan2
- CELA1 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CEP192 | c.426A>T p.Q142H | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CEP76 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CERS6 | c.567T>A p.Y189* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- CES1 | c.942+1G>T p.X314_splice | Splice Site (SNP) | VAF 99/508 reads (19%) | called by muse, mutect2, varscan2
- CES1 | c.572A>T p.H191L | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CFAP54 | c.3831G>C p.K1277N | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CFAP58 | c.2354A>T p.H785L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP70 | c.865del p.D290Ifs*20 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel*, varscan2
- CFAP70 | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by mutect2, varscan2
- CFC1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 56/770 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- CHAT | c.924C>A p.C308* | Nonsense Mutation (SNP) | VAF 48/283 reads (17%) | called by muse, mutect2, varscan2
- CHD9 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- CHRNA5 | c.308G>A p.W103* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- CHST7 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST8 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN3 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- CLEC16A | c.595A>T p.K199* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- CLEC16A | c.1574C>G p.P525R | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- CLVS2 | c.614G>A p.W205* | Nonsense Mutation (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- CNBP | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CNDP1 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA1 | c.1641C>A p.N547K | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CNIH3 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CNKSR1 | c.952C>G p.P318A (on ENST00000374253 / NM_001297647.2; = p.P311A on NM_006314.3) | Missense Mutation (SNP) | VAF 150/320 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CNTN1 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTN6 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.393del p.N132Ifs*30 | Frame Shift Del (DEL) | VAF 50/365 reads (14%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.2869T>A p.S957T | Missense Mutation (SNP) | VAF 78/822 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- COL12A1 | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- COL16A1 | c.2641C>G p.Q881E | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.3889G>A p.G1297R | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.3800G>T p.G1267V | Missense Mutation (SNP) | VAF 134/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 157/530 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- COL6A5 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 64/249 reads (26%) | called by muse, mutect2, varscan2
- COL6A5 | c.3245C>A p.P1082Q | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COL6A5 | c.5178G>A p.M1726I | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- COPE | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CORO7 | c.2457+3G>T | Splice Region (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- COX16 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CSN2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CST9 | c.149del p.T50Kfs*6 | Frame Shift Del (DEL) | VAF 66/286 reads (23%) | called by pindel, varscan2
- CT45A1 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 149/1656 reads (9%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.917); called by muse, varscan2
- CTBP1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- CTH | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNNA3 | c.2669G>T p.R890I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, varscan2
- CTNND2 | c.2543A>C p.K848T | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CUX2 | c.2175del p.S726Rfs*20 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- CWC22 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CYB5R2 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, varscan2
- CYBB | c.1188_1189delinsT p.E396Dfs*9 | Frame Shift Del (DEL) | VAF 49/365 reads (13%) | called by pindel, varscan2*
- CYP11A1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 199/518 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CYP26C1 | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); called by muse, varscan2
- CYP4F3 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- CYP7A1 | c.671_672del p.P224Hfs*41 | Frame Shift Del (DEL) | VAF 155/520 reads (30%) | called by mutect2, pindel, varscan2
- CYTIP | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DACH1 | c.1787G>T p.G596V (on ENST00000619232 / NM_001366712.1; = p.G342V on NM_004392.6) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.085); called by muse, mutect2
- DBF4 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF12L1 | c.944G>C p.C315S | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- DCHS2 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DCLK1 | c.2215C>A p.P739T (on ENST00000360631 / NM_001330072.2; = p.P432T on NM_001195416.2) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DCSTAMP | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 133/506 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DCT | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DDB1 | c.1410+6A>T | Splice Region (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- DDN | c.661T>C p.W221R | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX53 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX53 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX54 | c.2230G>T p.G744* | Nonsense Mutation (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2, varscan2
- DEFB127 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1B | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- DENND1B | c.175A>T p.R59W | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENND2A | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGLUCY | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DLD | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLG2 | c.2305-2A>T p.X769_splice | Splice Site (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- DLG2 | c.244del p.E82Rfs*93 (on ENST00000650630 / NM_001351274.2; = p.E45Rfs*93 on NM_001142699.3) | Frame Shift Del (DEL) | VAF 46/193 reads (24%) | called by mutect2, pindel, varscan2
- DLG3 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- DLGAP4 | c.1407G>T p.Q469H | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DMD | c.6019G>T p.V2007F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAAF1 | c.1029_1030del p.E345Dfs*6 | Frame Shift Del (DEL) | VAF 48/390 reads (12%) | called by pindel, varscan2
- DNAH11 | c.1907A>T p.K636I | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- DNAH14 | c.4267G>T p.V1423L (on ENST00000445597; = p.V1828L on NM_001367479.1) | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DNAH14 | c.7422A>T p.E2474D (on ENST00000445597; = p.E3127D on NM_001367479.1) | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.5155G>T p.A1719S | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DNAH9 | c.6818C>G p.T2273R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAH9 | c.9327G>T p.Q3109H | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DOCK10 | c.5305G>T p.G1769* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- DOCK10 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK11 | c.3284G>T p.R1095L | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DOCK11 | c.4952_4953del p.E1651Vfs*10 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | called by pindel, varscan2
- DPY19L2 | c.1165G>T p.G389* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- DRP2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DSCAML1 | c.4875G>C p.Q1625H (on ENST00000321322; = p.Q1565H on NM_020693.4) | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2
- DSG1 | c.2137C>A p.P713T | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DSG1 | c.2311C>A p.L771I | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- DTX1 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUSP11 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DUSP5 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- EAF2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EBF1 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- ECHDC3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EIF4G1 | c.1439G>T p.G480V (on ENST00000346169 / NM_198241.3; = p.G284V on NM_004953.5) | Missense Mutation (SNP) | VAF 129/453 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ELOA3 | c.911C>G p.A304G | Missense Mutation (SNP) | VAF 246/6094 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- EMC8 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- EMILIN3 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ENDOD1 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ENG | c.487A>G p.N163D | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHB6 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ERBIN | c.2900C>A p.S967Y | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ERF | c.92A>T p.H31L | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERVV-2 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.646); called by muse, varscan2
- ETS2 | c.720del p.K241Sfs*23 | Frame Shift Del (DEL) | VAF 125/538 reads (23%) | called by mutect2, pindel, varscan2
- EYS | c.3247T>A p.C1083S | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- F13A1 | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 156/502 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F8 | c.4498C>T p.P1500S | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- F8 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FAM111B | c.1765G>T p.G589C | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FAM135B | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- FAM13A | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM168B | c.517del p.H173Tfs*63 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- FAM186A | c.6281C>G p.P2094R | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- FANCM | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 66/254 reads (26%) | called by muse, mutect2, varscan2
- FAT1 | c.9764C>G p.A3255G | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FAT2 | c.9271G>T p.G3091C | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.1120dup p.I374Nfs*2 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | called by mutect2, pindel, varscan2
- FBRSL1 | c.2257G>T p.V753L | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FBXO10 | c.2041G>C p.G681R | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FBXO8 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCAMR | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FERD3L | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF3 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FKBP6 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.764); called by muse, mutect2
- FLG | c.3332C>A p.S1111Y | Missense Mutation (SNP) | VAF 199/802 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FLNC | c.6691C>A p.L2231M | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FLT1 | c.2885G>T p.S962I | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FMN2 | c.925del p.A309Qfs*143 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- FMO2 | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FOXJ1 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FOXN4 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FRAS1 | c.8191T>C p.F2731L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, varscan2
- FRMD6 | c.252del p.W84* | Frame Shift Del (DEL) | VAF 26/147 reads (18%) | called by mutect2, pindel, varscan2
- FRMD7 | c.1706A>T p.E569V | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRMPD4 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FSIP2 | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FSIP2 | c.12857T>A p.L4286Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FSIP2 | c.17852G>T p.S5951I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- G6PC2 | c.733A>T p.N245Y | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GABRE | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- GABRR1 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 64/571 reads (11%) | called by muse, mutect2, varscan2
- GALNT7 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAREM1 | c.2485G>T p.V829F (on ENST00000269209 / NM_001242409.2; = p.V828F on NM_022751.3) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- GART | c.2277A>C p.E759D | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCC2 | c.4838C>A p.A1613E | Missense Mutation (SNP) | VAF 47/960 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2
- GFRA1 | c.840A>T p.E280D | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- GFRA4 | c.622A>T p.N208Y (on ENST00000319242 / NM_145762.3; = p.N178Y on NM_022139.4) | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GLYATL3 | c.108dup p.G37Wfs*28 | Frame Shift Ins (INS) | VAF 25/215 reads (12%) | called by mutect2, pindel, varscan2
- GPER1 | c.904C>A p.H302N | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GPR42 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 113/1044 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GPR50 | c.1022A>T p.H341L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRASP2 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- GPRASP2 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.027); called by muse, mutect2
- HDAC9 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDC | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HDGFL1 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HEATR3 | c.1413G>T p.Q471H | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ | c.3509C>G p.P1170R | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- HEMGN | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, varscan2
- HERC2 | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HES3 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HGF | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HIP1 | c.1465-1G>A p.X489_splice | Splice Site (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- HMCN2 | c.5747T>G p.L1916R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMX3 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, varscan2
- HNF4A | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 96/376 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HNRNPUL1 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by mutect2, varscan2
- HOXA3 | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2
- HOXB3 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, varscan2
- HS3ST3A1 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 60/169 reads (36%) | called by muse, mutect2
- HS3ST3A1 | c.286T>G p.W96G | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- HSD17B8 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSD3B2 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSF4 | c.1236G>C p.L412F (on ENST00000521374 / NM_001040667.3; = p.L382F on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/607 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HTR1A | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HUS1B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- IARS2 | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ICAM1 | c.528_532del p.R177Sfs*11 | Frame Shift Del (DEL) | VAF 71/409 reads (17%) | called by mutect2, pindel, varscan2
- ICAM4 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE2 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IFIT1B | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFRD1 | c.95-2A>T p.X32_splice | Splice Site (SNP) | VAF 163/469 reads (35%) | called by muse, mutect2, varscan2
- IFT172 | c.2912C>A p.S971* | Nonsense Mutation (SNP) | VAF 110/259 reads (42%) | called by muse, mutect2, varscan2
- IFT88 | c.2187A>T p.K729N (on ENST00000319980 / NM_001318493.2; = p.K720N on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGFN1 | c.2306G>T p.G769V (on ENST00000295591 / NM_001367841.1; = p.G3226V on NM_001164586.2) | Missense Mutation (SNP) | VAF 104/400 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- IGHV4-31 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 68/1128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGKV1D-43 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 198/768 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- IL2RG | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ILDR2 | c.1344T>A p.S448R | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ILDR2 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- INPP5F | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- INTS3 | c.2207G>T p.R736L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INTS6L | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRS1 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ITGA11 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGAD | c.1401C>A p.D467E | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, varscan2
- ITIH2 | c.1999C>G p.P667A | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ITIH5 | c.1682G>T p.R561M | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ITIH6 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IZUMO2 | c.438G>T p.L146F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- JADE2 | c.1910A>T p.K637M | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KANK1 | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KCMF1 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KCNB1 | c.1611del p.K538Rfs*32 | Frame Shift Del (DEL) | VAF 35/176 reads (20%) | called by mutect2, pindel, varscan2
- KCNH5 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KCNK15 | c.779C>G p.T260S | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK2 | c.369del p.A124Qfs*2 (on ENST00000444842 / NM_001017425.3; = p.A109Qfs*2 on NM_014217.4) | Frame Shift Del (DEL) | VAF 29/243 reads (12%) | called by mutect2, pindel, varscan2
- KDM3B | c.2138G>T p.G713V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- KIAA1210 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 105/351 reads (30%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1755 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- KIF16B | c.1655A>G p.N552S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF21A | c.3608del p.G1203Vfs*19 (on ENST00000361418 / NM_001378440.1; = p.G1190Vfs*19 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 81/378 reads (21%) | called by mutect2, pindel, varscan2
- KIF6 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KIR2DL4 | c.119T>C p.M40T (on ENST00000396284; = p.M1? on NM_001080770.2) | Missense Mutation (SNP) | VAF 118/309 reads (38%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIRREL1 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | called by muse, mutect2, varscan2
- KLF11 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 144/293 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHDC2 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KLHL30 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 78/476 reads (16%) | called by muse, mutect2, varscan2
- KLHL38 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 159/527 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KNDC1 | c.330del p.E111Sfs*4 | Frame Shift Del (DEL) | VAF 86/331 reads (26%) | called by mutect2, pindel, varscan2
- KNDC1 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- KRT76 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KRTAP11-1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-7 | c.141C>A p.S47R | Missense Mutation (SNP) | VAF 107/584 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- KRTAP22-2 | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 45/180 reads (25%) | PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- LAMB2 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- LAS1L | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAX1 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- LBP | c.1217+2T>A p.X406_splice | Splice Site (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- LDHD | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- LGSN | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LIG4 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 37/378 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2
- LINGO1 | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIPG | c.1376+1G>C p.X459_splice | Splice Site (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- LMO4 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 116/282 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LNPK | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LRBA | c.5407G>T p.A1803S | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LRFN2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRFN5 | c.235del p.D79Tfs*2 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- LRIG3 | c.1585C>G p.P529A | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- LRIG3 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.6204G>T p.W2068C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.803del p.G268Efs*3 | Frame Shift Del (DEL) | VAF 50/243 reads (21%) | called by mutect2, pindel, varscan2
- LRRC28 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 151/423 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- LRRIQ1 | c.3800G>T p.W1267L | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LY75 | c.3502C>T p.Q1168* | Nonsense Mutation (SNP) | VAF 81/305 reads (27%) | called by muse, mutect2, varscan2
- LZTR1 | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAEL | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MAGEB6B | c.370del p.S124Lfs*55 | Frame Shift Del (DEL) | VAF 38/195 reads (19%) | called by mutect2, pindel, varscan2
- MAGED2 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MAGEL2 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- MAP1S | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.439); called by mutect2, varscan2
- MAP2K6 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 68/134 reads (51%) | called by muse, mutect2, varscan2
- MARCHF7 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.177); called by muse, mutect2
- ME1 | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MGAM | c.4064G>T p.W1355L | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- MGAM2 | c.6506C>A p.T2169N | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- MIB2 | c.2821G>T p.G941W | Missense Mutation (SNP) | VAF 173/357 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MICALL2 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MKI67 | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, varscan2
- MMRN2 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MNAT1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MNX1 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 128/794 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD2 | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MPDZ | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MR1 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 83/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRGPRD | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- MROH2B | c.1319A>T p.D440V | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
868 further variants in this file (359 protein-altering or splice-affecting, 312 silent, 197 other) are not listed here.
